Somatic mutation profile of tumor specimen BA2652D (aliquot aq-BA2652D) from BEATAML1.0 case 2430, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.7 years (18,514 days).
Specimen BA2652D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd39a6d9-53fe-4894-bd0d-10787d536069.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2447D (Solid Tissue Normal), aliquot aq-BA2447D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6343ef76-fdd7-4321-a6d0-470ef534fe43

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.6091C>T p.R2031C | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs759981264, COSV56522180; called by muse, mutect2, varscan2
- CEBPA | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57196839, COSV57200991; called by muse, mutect2, varscan2
- LRP12 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); catalogued as rs746849847; called by muse, mutect2, varscan2
- NEURL4 | c.1107G>T p.K369N | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100224313; called by muse, mutect2
- VAX2 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs781980710; called by muse, varscan2
- CLIP3 | c.578G>T p.C193F | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PRKAG1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRKCA | c.1726C>A p.H576N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2
- RASGRF1 | c.3659T>A p.M1220K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WRNIP1 | c.1521C>A p.H507Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2
- HERC2 | c.5403C>T p.N1801= | Silent (SNP) | VAF 59/240 reads (25%) | called by muse, mutect2, varscan2
- ITGB6 | c.354G>A p.A118= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs766609352, COSV99324108; called by muse, mutect2
- MAP3K21 | c.1590C>T p.N530= | Silent (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- UPK1A | c.672C>T p.H224= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs368676781; called by muse, varscan2
- VWA3A | c.333C>T p.S111= | Silent (SNP) | VAF 33/126 reads (26%) | catalogued as rs773543858; called by muse, mutect2, varscan2
- WDR93 | c.513T>C p.F171= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as rs772565628; called by muse, mutect2, varscan2
